Somatic mutation profile of tumor specimen TCGA-MT-A51X-01A (aliquot TCGA-MT-A51X-01A-11D-A25Y-08) from TCGA case TCGA-MT-A51X, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 30.1 years (10,976 days).
Specimen TCGA-MT-A51X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe91aeb9-c4bc-440d-b3c0-9294134a180b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MT-A51X-10A (Blood Derived Normal), aliquot TCGA-MT-A51X-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3920d546-6e35-4352-a8bb-ef64671d69ce

The open-access MAF lists 57 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Nonsense Mutation 5, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.4831C>T p.R1611* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | catalogued as rs1554236040, COSV51670259; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BTD | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587783005, CM146369, COSV100329690; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACSL3 | c.1373C>A p.T458N | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.139); catalogued as COSV100658011; called by mutect2, varscan2
- ADAMTS5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286298815, COSV53175922; called by muse, mutect2, varscan2
- ASIC5 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as rs958536874, COSV101539775; called by muse, mutect2
- CAMTA1 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 21/102 reads (21%) | catalogued as COSV100351502; called by muse, mutect2, varscan2
- CAND1 | c.1315C>T p.L439F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV101607336; called by muse, mutect2, varscan2
- CCDC88B | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV100105667; called by muse, mutect2
- CFHR3 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100807676; called by mutect2, varscan2
- DAB1 | c.1669G>T p.A557S (on ENST00000371231; = p.A524S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as COSV100976455; called by muse, mutect2, varscan2
- DCTPP1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1010468456, COSV100073581; called by muse, mutect2, varscan2
- DLC1 | c.1870G>A p.V624I (on ENST00000276297 / NM_001348081.2; = p.V187I on NM_006094.5) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52320376; called by muse, mutect2, varscan2
- DUSP16 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.184); catalogued as rs748787807, COSV99963277; called by muse, mutect2
- HDC | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | catalogued as rs773638414, COSV51068237; called by muse, mutect2, varscan2
- HERC2 | c.10712C>T p.A3571V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs151205330; called by muse, mutect2
- IFIT3 | c.104A>T p.E35V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99260686; called by muse, mutect2, varscan2
- ITGA10 | c.2339A>T p.Q780L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100994978; called by muse, varscan2
- ITGAX | c.27_29del p.L10del | In Frame Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs1243624138; called by pindel, varscan2
- KRT33B | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV52443114; called by muse, mutect2
- LOXL3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs374759905; called by mutect2, varscan2
- MAGI3 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs1370263133, COSV56833761; called by muse, mutect2
- MAP1A | c.226G>T p.V76L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100288948; called by muse, mutect2
- MPDZ | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV100063655; called by muse, varscan2
- MRPL24 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100625823; called by muse, mutect2, varscan2
- MSR1 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100027629; called by muse, mutect2, varscan2
- NRXN1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as rs200247365, COSV101278010; called by muse, mutect2
- PLEKHG3 | c.3022C>T p.R1008C (on ENST00000394691; = p.R1064C on NM_001308147.2) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.276); catalogued as rs200998943, COSV55977547; called by muse, mutect2, varscan2
- PRKCQ | c.1445+1G>A p.X482_splice | Splice Site (SNP) | VAF 53/274 reads (19%) | catalogued as rs1190765193, COSV54111433; called by muse, mutect2, varscan2
- RAD54B | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279995; called by muse, mutect2
- RBMXL2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV100182106, COSV100182368; called by muse, mutect2
- RUNX1T1 | c.1372C>T p.R458C (on ENST00000265814 / NM_001198628.1; = p.R431C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1381105316, COSV56138759; called by muse, mutect2, varscan2
- SFRP4 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.781); catalogued as COSV99554564; called by muse, mutect2, varscan2
- SLC19A1 | c.1761G>C p.Q587H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100229503; called by muse, mutect2, varscan2
- SLC6A17 | c.1617G>T p.E539D | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100521425; called by muse, mutect2, varscan2
- SLITRK3 | c.978C>A p.Y326* | Nonsense Mutation (SNP) | VAF 27/261 reads (10%) | catalogued as COSV99579630; called by muse, mutect2, varscan2
- SYBU | c.65G>A p.R22Q (on ENST00000276646 / NM_001099754.2; = p.R21Q on NM_017786.6) | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1405679757, COSV99406206; called by muse, mutect2
- TLN1 | c.1110T>G p.F370L | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as COSV100147985; called by muse, mutect2
- USH2A | c.15260C>T p.S5087F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100238674; called by muse, mutect2, varscan2
- ZNF497 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775601110, COSV99568464; called by muse, mutect2, varscan2
- CCL25 | c.170G>T p.S57I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD11 | c.4701G>A p.R1567= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs1470878405, COSV99970077; called by muse, mutect2, varscan2
- ASXL1 | c.951T>C p.A317= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100040301; called by muse, mutect2, varscan2
- CSMD1 | c.9303G>A p.P3101= (on ENST00000520002; = p.P3100= on NM_033225.6) | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as rs761115346, COSV59281702, COSV59317968; called by muse, varscan2
- CSMD2 | c.6603G>A p.P2201= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs758754654, COSV99592535; called by muse, mutect2, varscan2
- EBF1 | c.1467C>T p.N489= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1198772077, COSV58186181; called by muse, mutect2
- EEA1 | c.276C>A p.V92= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV100468174; called by muse, mutect2, varscan2
- ELFN2 | c.630C>T p.Y210= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs558029911, COSV101297593; called by muse, mutect2, varscan2
- FAM47B | c.1290C>T p.T430= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1350753109, COSV100264784, COSV61456172; called by muse, mutect2, varscan2
- GABRB1 | c.1158C>T p.S386= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV55003384; called by muse, mutect2, varscan2
- HECTD4 | c.2430G>C p.V810= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100296138; called by muse, mutect2, varscan2
- OR56A3 | c.96C>T p.S32= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1222707273, COSV100290324; called by muse, mutect2, varscan2
- ST3GAL5 | c.843C>T p.I281= (on ENST00000377332; = p.I321= on NM_003896.4) | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100088556; called by muse, mutect2, varscan2
- TRAPPC1 | c.222C>T p.Y74= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as rs773796149, COSV58051183; called by muse, mutect2, varscan2
- TRPM3 | c.2073C>T p.D691= (on ENST00000357533 / NM_001366142.2; = p.D534= on NM_020952.6) | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs530661575, COSV62596033; called by muse, mutect2, varscan2
- UAP1 | c.882A>G p.R294= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs745904306, COSV99617870; called by muse, mutect2, varscan2
- UNC93B1 | c.834G>A p.T278= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV57098427, COSV99916456; called by muse, mutect2, varscan2
- NACA | c.71-3107G>A | Intron (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100771460; called by muse, varscan2
